Somatic mutation profile of tumor specimen TCGA-2G-AAFN-01A (aliquot TCGA-2G-AAFN-01A-31D-A42Y-10) from TCGA case TCGA-2G-AAFN, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 26.8 years (9,805 days).
Specimen TCGA-2G-AAFN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13c7f263-9dba-4747-8f97-9632725c5965.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAFN-10A (Blood Derived Normal), aliquot TCGA-2G-AAFN-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c49fa3a6-f5aa-44a4-a118-b64558f1c467

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 5, Silent 4, Nonsense Mutation 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SAGE1 | c.2238G>C p.E746D | Missense Mutation (SNP) | VAF 48/243 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.712); catalogued as COSV100187706; called by muse, mutect2, varscan2
- SNX20 | c.914C>A p.T305N | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.307); catalogued as COSV56058602; called by muse, mutect2, varscan2
- SPESP1 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs142183563; called by muse, mutect2
- TNK1 | c.1369G>T p.G457C (on ENST00000576812 / NM_001251902.2; = p.G452C on NM_003985.5) | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as rs1237929259, COSV100247785; called by muse, mutect2
- CYP1A1 | c.382G>T p.G128* | Nonsense Mutation (SNP) | VAF 22/89 reads (25%) | called by muse, mutect2, varscan2
- DNAI3 | c.1569G>A p.W523* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- MARS1 | c.224G>A p.W75* | Nonsense Mutation (SNP) | VAF 23/116 reads (20%) | called by muse, mutect2, varscan2
- RPL5 | c.528-7_528-4del | Splice Region (DEL) | VAF 61/323 reads (19%) | called by mutect2, pindel, varscan2
- TBCE | c.194C>G p.T65R | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.781); called by muse, mutect2
- DNASE2B | c.942C>T p.G314= | Silent (SNP) | VAF 13/302 reads (4%) | called by muse, mutect2
- GTF2A1 | c.291T>A p.P97= | Silent (SNP) | VAF 30/87 reads (34%) | called by muse, mutect2, varscan2
- PCDH18 | c.2412T>C p.S804= | Silent (SNP) | VAF 52/106 reads (49%) | called by muse, mutect2, varscan2
- SEPTIN6 | c.762G>C p.R254= | Silent (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
